Somatic mutation profile of tumor specimen TCGA-CC-A7IE-01A (aliquot TCGA-CC-A7IE-01A-21D-A382-10) from TCGA case TCGA-CC-A7IE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.5 years (20,985 days).
Specimen TCGA-CC-A7IE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 598ab81d-a2c9-47dd-9a41-660b3c39a943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IE-10A (Blood Derived Normal), aliquot TCGA-CC-A7IE-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/205003ad-64ef-4349-91b9-01c615689fae

The open-access MAF lists 183 somatic variants for this specimen: 140 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 36, Splice Site 9, Nonsense Mutation 7, Frame Shift Del 6, Intron 3, RNA 3, Frame Shift Ins 3, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.163); catalogued as COSV99933169; called by muse, mutect2, varscan2
- ABCG4 | c.1561G>C p.G521R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100266483; called by muse, mutect2, varscan2
- ACVR1B | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231237; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1934G>C p.R645P | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM148081; called by muse, mutect2, varscan2
- ADGRF5 | c.1631A>G p.H544R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV99344834; called by muse, mutect2, varscan2
- ANGPTL4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100034996; called by muse, mutect2, varscan2
- ANKRD17 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV100428487; called by muse, mutect2
- APBB3 | c.59G>C p.W20S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761240609, COSV100021072, COSV60053543; called by muse, mutect2
- ARID2 | c.925A>T p.N309Y | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100535317, COSV57596504; called by muse, mutect2, varscan2
- ARID2 | c.4774-2A>G p.X1592_splice | Splice Site (SNP) | VAF 24/67 reads (36%) | catalogued as COSV57599948; called by muse, mutect2, varscan2
- BASP1 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV100493487, COSV59472247; called by muse, mutect2, varscan2
- BCAM | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV99538464; called by muse, mutect2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs751794665; called by mutect2, varscan2
- C8orf58 | c.1033C>T p.R345W (on ENST00000289989 / NM_001013842.3; = p.R337W on NM_173686.3) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs373658775; called by muse, mutect2, varscan2
- CCDC144A | c.3892A>G p.N1298D | Missense Mutation (SNP) | VAF 98/329 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as rs558127337, COSV100138292; called by muse, mutect2, varscan2
- CELSR3 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99372447; called by muse, mutect2, varscan2
- CGNL1 | c.1622A>G p.K541R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV99847366; called by muse, mutect2, varscan2
- CHL1 | c.1681A>G p.I561V (on ENST00000397491 / NM_001253387.1; = p.I577V on NM_006614.4) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99849949; called by muse, mutect2
- CHRNA2 | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs770447351, COSV99531861; called by muse, mutect2, varscan2
- CNOT6 | c.1639C>G p.Q547E | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs746498654, COSV99993384; called by muse, mutect2, varscan2
- CPS1 | c.1196A>G p.K399R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV99242043; called by muse, mutect2, varscan2
- CPXM2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV53870512, COSV99580921; called by muse, mutect2, varscan2
- CPZ | c.551G>A p.R184H (on ENST00000360986 / NM_001014447.3; = p.R173H on NM_003652.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs376798665; called by muse, mutect2, varscan2
- CR2 | c.1992T>A p.H664Q | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100889519; called by muse, mutect2, varscan2
- CRISP1 | c.66+1G>T p.X22_splice | Splice Site (SNP) | VAF 112/389 reads (29%) | catalogued as COSV100236572; called by muse, mutect2, varscan2
- CROCC | c.2417G>T p.G806V | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.899); catalogued as COSV100978041; called by muse, mutect2
- CRP | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99660417, COSV99660609; called by muse, mutect2, varscan2
- CSMD3 | c.7469T>A p.V2490E (on ENST00000297405 / NM_001363185.1; = p.V2386E on NM_052900.3) | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823438; called by muse, mutect2, varscan2
- CXXC4 | c.1083A>T p.E361D | Missense Mutation (SNP) | VAF 102/487 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.553); catalogued as COSV101182247; called by muse, mutect2, varscan2
- DGAT2L6 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV100283872; called by muse, mutect2, varscan2
- DNAH3 | c.3287T>C p.I1096T | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753509012, COSV99764731; called by muse, mutect2, varscan2
- DOCK10 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1305763186, COSV51420167; called by muse, mutect2, varscan2
- DSE | c.1249T>C p.F417L | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100528305, COSV59062524; called by muse, mutect2, varscan2
- DYDC1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs140462481, COSV64730883; called by muse, mutect2, varscan2
- EIF2AK4 | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.119); catalogued as rs756692952, COSV99774007; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100348835; called by muse, mutect2, varscan2
- EPHA4 | c.2093T>C p.I698T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99915434; called by muse, mutect2, varscan2
- FAM151B | c.544T>C p.W182R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV99971564; called by muse, mutect2, varscan2
- FAM98A | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 59/220 reads (27%) | catalogued as COSV99479004; called by muse, mutect2, varscan2
- FAT3 | c.3904G>T p.G1302* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as rs568235366, COSV99961430; called by muse, mutect2, varscan2
- FAXC | c.599+1G>T p.X200_splice | Splice Site (SNP) | VAF 20/73 reads (27%) | catalogued as COSV101067031; called by muse, mutect2, varscan2
- FAXC | c.599G>C p.W200S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101067032; called by muse, mutect2, varscan2
- FCGRT | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368383274, COSV99571134; called by mutect2, varscan2
- FNDC3A | c.1060A>G p.I354V (on ENST00000492622 / NM_001079673.2; = p.I298V on NM_014923.5) | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759840570, COSV101256587; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.733G>T p.G245* | Nonsense Mutation (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100435432; called by muse, mutect2, varscan2
- FREM2 | c.4828G>C p.E1610Q | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as COSV99746633; called by muse, mutect2, varscan2
- GAS7 | c.425C>A p.P142Q (on ENST00000432992 / NM_201433.2; = p.P82Q on NM_201432.2) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.146); catalogued as COSV100094381; called by muse, mutect2, varscan2
- GGTLC2 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as COSV101312175; called by muse, mutect2, varscan2
- GNAT3 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1422975389, COSV101242349; called by muse, mutect2, varscan2
- GPAA1 | c.1692G>T p.W564C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100731063; called by muse, mutect2, varscan2
- H4C4 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.538); catalogued as rs749934539, COSV61590686, COSV61591118; called by muse, mutect2, varscan2
- IGF1R | c.2577T>A p.N859K | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99148393; called by muse, mutect2, varscan2
- IL2RB | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344623; called by muse, mutect2, varscan2
- KCNT1 | c.483+1G>T p.X161_splice (on ENST00000488444; = p.X180_splice on NM_020822.3) | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99704882; called by muse, mutect2, varscan2
- KIAA0232 | c.1184A>T p.E395V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.618); catalogued as COSV100300315; called by muse, mutect2, varscan2
- KIAA1210 | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as rs1396793951, COSV101273898; called by muse, mutect2, varscan2
- KIAA1841 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV99693234; called by muse, mutect2, varscan2
- KIF3C | c.1497C>G p.D499E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV99266994; called by muse, mutect2, varscan2
- KRT10 | c.1461C>A p.H487Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); catalogued as COSV99509876; called by muse, mutect2
- LAMB4 | c.3958T>C p.S1320P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.694); catalogued as COSV99222569; called by muse, mutect2, varscan2
- LRP3 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV99472847; called by muse, mutect2
- LRP6 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs1323100850, COSV53784711; called by muse, mutect2, varscan2
- LRRIQ3 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100598440; called by muse, mutect2, varscan2
- MACF1 | c.8060A>T p.K2687M | Missense Mutation (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99240939; called by muse, mutect2, varscan2
- MAN2A1 | c.2669A>G p.N890S | Missense Mutation (SNP) | VAF 169/448 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV99810372; called by muse, mutect2, varscan2
- MAPK10 | c.511G>A p.G171R (on ENST00000359221 / NM_001351625.2; = p.G209R on NM_002753.5) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100173685; called by muse, mutect2, varscan2
- MARCHF4 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV56107712, COSV99814035; called by muse, mutect2, varscan2
- MCTP2 | c.2024T>A p.M675K | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100537186; called by muse, mutect2, varscan2
- MEP1A | c.1934A>T p.Q645L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV100042294; called by muse, mutect2, varscan2
- MGAT4C | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as COSV100152593; called by muse, mutect2, varscan2
- MGAT5B | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1280364387, COSV100047185; called by muse, mutect2
- MRPL21 | c.450-2A>G p.X150_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as rs1285583963, COSV100751873; called by muse, mutect2, varscan2
- MRPS26 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV99848578; called by muse, mutect2, varscan2
- MYCBP2 | c.11834G>C p.R3945T (on ENST00000357337; = p.R3983T on NM_015057.5) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV62044622; called by muse, mutect2, varscan2
- MYCBP2 | c.5692C>G p.P1898A (on ENST00000357337; = p.P1936A on NM_015057.5) | Missense Mutation (SNP) | VAF 220/686 reads (32%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.956); catalogued as COSV100629117; called by muse, mutect2, varscan2
- MYH8 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs753981095, COSV67963691; called by muse, mutect2, varscan2
- MYO18B | c.4642A>G p.T1548A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV100122494; called by muse, mutect2, varscan2
- MYO18B | c.5657A>T p.Q1886L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV100122495; called by muse, mutect2, varscan2
- NCOR1 | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99246898; called by muse, mutect2, varscan2
- NEK10 | c.3471-2A>T p.X1157_splice | Splice Site (SNP) | VAF 92/162 reads (57%) | catalogued as COSV99834730; called by muse, mutect2, varscan2
- NEUROD4 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV99669688; called by muse, mutect2, varscan2
- NISCH | c.3829T>G p.S1277A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100401118; called by muse, mutect2, varscan2
- NPBWR2 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100871072; called by muse, mutect2, varscan2
- NTRK2 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV99452138; called by muse, mutect2, varscan2
- OR8H2 | c.840T>G p.I280M | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.988); catalogued as COSV100542124; called by muse, mutect2, varscan2
- PAPSS2 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV100753398; called by muse, mutect2, varscan2
- PCDHB16 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53358582, COSV99500949; called by muse, mutect2, varscan2
- PCDHB2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV50565755; called by muse, mutect2, varscan2
- PCK2 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV99394079; called by muse, mutect2, varscan2
- PKD1 | c.9853G>A p.V3285I | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201780393, CM014078, COSV99237078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKP2 | c.226A>C p.N76H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99297167; called by muse, mutect2, varscan2
- PLCE1 | c.6720+2T>C p.X2240_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | catalogued as COSV99593301; called by muse, mutect2, varscan2
- PXDNL | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs760653043, COSV100680987; called by muse, mutect2, varscan2
- RBM12 | c.1637C>A p.A546D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100466937, COSV58296067; called by muse, mutect2, varscan2
- SARM1 | c.1853T>G p.V618G | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99134920; called by muse, mutect2, varscan2
- SCN1A | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100319138; called by muse, mutect2, varscan2
- SEC31B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100944790; called by muse, mutect2, varscan2
- SETD2 | c.6967T>G p.Y2323D | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337894; called by muse, mutect2, varscan2
- SLC5A10 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1215372222, COSV58761970; called by muse, mutect2, varscan2
- SLC6A5 | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100116377, COSV100116725; called by muse, mutect2, varscan2
- SLC8A1 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60478133; called by muse, mutect2, varscan2
- SLFN11 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57698562; called by muse, mutect2, varscan2
- SMR3A | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV99895495; called by muse, mutect2, varscan2
- SOX30 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs758531533, COSV53938967; called by muse, mutect2, varscan2
- SPEG | c.8078C>T p.T2693M | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200879669, COSV100403166; called by muse, mutect2, varscan2
- SPTA1 | c.6968T>A p.L2323Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs536323126, COSV100934156; called by muse, mutect2, varscan2
- SPTA1 | c.4952T>A p.L1651Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100934157; called by muse, mutect2
- SRCAP | c.8585G>T p.R2862M | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV99349168; called by muse, mutect2, varscan2
- SRCAP | c.8586G>T p.R2862S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV99349171; called by muse, mutect2, varscan2
- SRRM4 | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99937645; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 38/145 reads (26%) | PolyPhen probably damaging (0.995); catalogued as rs779190621, COSV59562875; called by muse, mutect2, varscan2
- SUPV3L1 | c.1787A>G p.Q596R | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV100669480; called by muse, mutect2, varscan2
- TAF3 | c.2531T>A p.V844E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100719795; called by muse, mutect2, varscan2
- THAP10 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs544136510, COSV51436552; called by muse, mutect2, varscan2
- TLX3 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs368190023; called by muse, mutect2, varscan2
- TLX3 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99740426; called by muse, mutect2, varscan2
- TMCC3 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV99705150; called by muse, mutect2, varscan2
- TMEM59 | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV52372879; called by muse, mutect2, varscan2
- TRDN | c.1343A>T p.E448V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100520767; called by muse, mutect2, varscan2
- TTC31 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs368112249, COSV52037578, COSV99281881; called by muse, mutect2, varscan2
- TYSND1 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs143461435; called by mutect2, varscan2
- UMODL1 | c.1900-1G>A p.X634_splice (on ENST00000408910 / NM_001004416.2; = p.Q761= on NM_173568.3) | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as COSV100210501; called by muse, mutect2, varscan2
- USP2 | c.1622A>G p.Y541C | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489281; called by muse, mutect2, varscan2
- WASF1 | c.92A>T p.N31I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661020; called by muse, mutect2, varscan2
- XPO6 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as COSV100484651; called by muse, mutect2, varscan2
- ZEB2 | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100354876; called by muse, mutect2, varscan2
- ZEB2 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as COSV100354878; called by muse, mutect2, varscan2
- ZNF75A | c.872A>T p.H291L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV101556596; called by muse, mutect2, varscan2
- ABHD4 | c.231dup p.G78Wfs*44 | Frame Shift Ins (INS) | VAF 26/100 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1832A>T p.E611V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD17 | c.6891del p.L2297Ffs*36 | Frame Shift Del (DEL) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- GDF2 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLE1 | c.617_624del p.K206Tfs*58 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MAP4K5 | c.1767dup p.P590Tfs*29 | Frame Shift Ins (INS) | VAF 23/207 reads (11%) | called by mutect2, pindel, varscan2
- NCOA2 | c.381_383del p.F128del | In Frame Del (DEL) | VAF 28/152 reads (18%) | called by pindel, varscan2
- NCOR2 | c.1142_1143del p.E381Afs*22 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | called by pindel, varscan2
- RPS6 | c.661_682del p.K221Lfs*26 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- SELENOO | c.601_602del p.L201Mfs*32 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- SUSD6 | c.411del p.L138Cfs*9 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel*, varscan2
- ADAMTS14 | c.3150C>G p.P1050= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs1259697796, COSV100941323; called by muse, mutect2, varscan2
- AHNAK2 | c.7089C>T p.T2363= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV100315329; called by muse, mutect2, varscan2
- C1QL3 | c.168C>T p.P56= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs749672191, COSV100126923; called by muse, mutect2, varscan2
- CACNA1E | c.303C>A p.A101= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV100701263; called by muse, mutect2, varscan2
- CBX3 | c.93C>T p.V31= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs575959807, COSV61761239, COSV61761748; called by muse, mutect2
- CHIA | c.852C>T p.P284= (on ENST00000343320; = p.P176= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV100588554; called by muse, mutect2, varscan2
- COL12A1 | c.4755T>C p.F1585= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs746556967, COSV100485321; called by muse, mutect2, varscan2
- CYP2W1 | c.909C>T p.A303= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as COSV100417103; called by muse, mutect2, varscan2
- CYP4A11 | c.1506C>A p.I502= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as COSV100152151; called by muse, mutect2, varscan2
- DNAH17 | c.5250G>A p.R1750= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101101327, COSV104433108; called by muse, mutect2, varscan2
- EPG5 | c.1197A>G p.A399= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV56354463; called by muse, mutect2, varscan2
- GC | c.171T>C p.F57= | Silent (SNP) | VAF 14/226 reads (6%) | catalogued as COSV99909364; called by muse, mutect2
- GRM5 | c.1038A>G p.P346= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs1400126122, COSV100550012; called by muse, mutect2, varscan2
- IGSF10 | c.5028C>T p.P1676= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99176585; called by muse, mutect2, varscan2
- KCNS2 | c.114C>T p.F38= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs778298625, COSV99750666; called by muse, mutect2, varscan2
- LRP1B | c.12324T>G p.S4108= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs1217223341, COSV101251755; called by muse, mutect2, varscan2
- MAB21L4 | c.474A>G p.A158= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100278387; called by muse, mutect2, varscan2
- MACC1 | c.1044T>A p.V348= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV100255291; called by muse, mutect2, varscan2
- MYH7 | c.5475G>A p.E1825= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs1353101205, COSV100805661; called by muse, mutect2, varscan2
- NAALADL2 | c.1401T>A p.T467= | Silent (SNP) | VAF 37/297 reads (12%) | catalogued as COSV101379870; called by muse, mutect2, varscan2
- NOS1AP | c.1227T>C p.A409= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100722788; called by muse, mutect2, varscan2
- NOS2 | c.1824G>A p.S608= | Silent (SNP) | VAF 65/216 reads (30%) | catalogued as rs759255233, COSV100569464, COSV58224650; called by muse, mutect2, varscan2
- PCBP3 | c.852A>G p.S284= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV101234244; called by muse, mutect2, varscan2
- PPARA | c.201C>T p.V67= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99415085; called by muse, mutect2, varscan2
- PRSS37 | c.234G>A p.Q78= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV100633786; called by muse, mutect2, varscan2
- RECQL4 | c.3447G>A p.L1149= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV56740300, COSV56743001; called by muse, mutect2
- RIT2 | c.207C>T p.Y69= | Silent (SNP) | VAF 112/327 reads (34%) | catalogued as COSV99949501; called by muse, mutect2, varscan2
- SH3GL1 | c.66A>T p.G22= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99522467; called by muse, mutect2, varscan2
- SHROOM4 | c.3981C>A p.V1327= | Silent (SNP) | VAF 60/106 reads (57%) | catalogued as rs1459368392, COSV99172976; called by muse, mutect2, varscan2
- SLC12A2 | c.3324T>A p.I1108= | Silent (SNP) | VAF 57/329 reads (17%) | catalogued as COSV99320495; called by muse, mutect2, varscan2
- SLC5A10 | c.249C>A p.G83= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs370923912, COSV100524763; called by muse, mutect2, varscan2
- SLITRK3 | c.1197C>T p.N399= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV99578430; called by muse, mutect2
- SPTA1 | c.609C>T p.F203= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV100934158, COSV63757464; called by muse, mutect2, varscan2
- TAB2 | c.1518C>A p.L506= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as COSV99644467; called by muse, mutect2, varscan2
- ZMYM5 | c.1497A>G p.T499= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV100562515; called by muse, mutect2, varscan2
- ZNF7 | c.810A>G p.R270= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as COSV100295620; called by muse, mutect2, varscan2
- ANK2 | c.2900+5161C>T | Intron (SNP) | VAF 18/86 reads (21%) | catalogued as rs1159398317, COSV99999391; called by muse, mutect2, varscan2
- BCAP29 | chr7:107621676 C>T | 3'Flank (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99143578; called by muse, mutect2, varscan2
- CCDC144B | n.286G>T | RNA (SNP) | VAF 71/221 reads (32%) | called by muse, mutect2, varscan2
- DCHS2 | n.2240A>T | RNA (SNP) | VAF 39/161 reads (24%) | catalogued as COSV100250781; called by muse, mutect2, varscan2
- MACROD2 | c.1315+3329C>A | Intron (SNP) | VAF 33/134 reads (25%) | catalogued as COSV53962210, COSV54060346; called by muse, mutect2, varscan2
- PCSK6 | c.2699+113_2699+117del | Intron (DEL) | VAF 10/72 reads (14%) | called by mutect2, varscan2
- SLC22A17 | n.1907C>G | RNA (SNP) | VAF 21/36 reads (58%) | catalogued as COSV99248475; called by muse, mutect2, varscan2
